Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A8FN, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A8FN-01A (Primary Tumor).

[page 1 of 2]
Collection Date:

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, LYMPHADENECTOMY -
TWELVE LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA (0/12).

PART 2: LYMPH NODES, LEFT PELVIC, LYMPHADENECTOMY -
TWELVE LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA (0/12).

PART 3: ANTERIOR FAT PAD, RESECTION -
A. ONE LYMPH NODE, NO EVIDENCE OF METASTATIC CARCINOMA (0/1).
B. FIBROADIPOSE TISSUE AND FIBROVASCULAR TISSUE.

PART 4: PROSTATE, RADICAL RETROPUBIC PROSTATECTOMY -
A. INVASIVE PROSTATIC ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7.
B. THE TUMOR INVOLVES BOTH THE RIGHT AND THE LEFT LOBES OF THE PROSTATE AND CONSTITUTES LESS THAN 5% OF THE TOTAL TISSUE EVALUATED.
C. THE CARCINOMA MEASURES 1.5 CM IN GREATEST NODULAR DIMENSION.
D. THE CARCINOMA IS CONFINED WITHIN THE CAPSULE OF THE PROSTATE.
E. BILATERAL SEMINAL VESICLES, NO CARCINOMA SEEN.
F. ALL MARGINS OF RESECTION ARE FREE OF CARCINOMA.
G. PERINEURAL INVASION BY THE CARCINOMA IS IDENTIFIED.
H. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN) IS SEEN.
I. TNM STAGE: pT2c N0 MX.
J. HISTOLOGIC GRADE: G3 (POORLY DIFFERENTIATED).

*Pw TSS -
Gleason 4+3 - dx discrepancy form -
BCA*

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA: PSA value: 6.8
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
PRIMARY GLEASON GRADE: 3
SECONDARY GLEASON GRADE: 4
GLEASON SUM SCORE: 7
GLEASON 4/5 PERCENTAGE: 35%
WEIGHT OF PROSTATE: 47.71gm
TUMOR SIZE: Maximum dimension: 1.5 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: < 5% of specimen involved by invasive tumor
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - multifocal

EXTRAPROSTATIC EXTENSION: No
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
RESIDUAL TUMOR: R0
LYMPH NODES EXAMINED: 25
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT2c
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

*ICD-O-3
Adenocarcinoma NOS 8140/3
Prostate NOS 61.9
7/11/29/13*

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form 4.05 ☒

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Prostate adenocarcinoma -	Age:	N/A
Event:	PathDiscrepancy)	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form		Provide the tumor identifier documented on the initial case quality control form for this case.
Pathologic Diagnosis Provided on Initial Pathology Report	Invasive prostatic adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
Histologic features of the sample provided for TCGA, as reflected on the CQCF	NA	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.
Discrepancy between Pathology Report and Case Quality Control Form		
Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form	the piece of tissue submitted has a different gleason score	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
Name of TSS Reviewing Pathologist or Biorepository Director	Provide the name of the pathologist who reviewed this case for TCGA.	

GLEASON SCORE OF TISSUE SUBMITTED IS 4+3=7
GLEASON SCORE OF CASE 3+4=7

Source: NCI Genomic Data Commons file 316832d2-81a0-4be0-a4d0-a7a298ece618 (TCGA-EJ-A8FN.FCAC56D3-5775-4A05-A739-108C8FBC9FD8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).